Somatic mutation profile of tumor specimen TCGA-CC-A7IJ-01A (aliquot TCGA-CC-A7IJ-01A-11D-A33Q-10) from TCGA case TCGA-CC-A7IJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 56.8 years (20,751 days).
Specimen TCGA-CC-A7IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a4dd234-9de8-4a34-a971-a784d708f5d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IJ-10A (Blood Derived Normal), aliquot TCGA-CC-A7IJ-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6837316-0d19-4b24-9b11-e8b380c60025

The open-access MAF lists 158 somatic variants for this specimen: 124 protein-altering or splice-affecting, 33 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 33, Frame Shift Del 5, Splice Site 3, Nonsense Mutation 3, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 37/61 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV66071866; called by muse, mutect2, varscan2
- ACSM2B | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100312661, COSV100312899; called by muse, mutect2
- ADAMTS20 | c.5333G>A p.C1778Y | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67141590; called by muse, mutect2, varscan2
- AKAP11 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV50305649; called by muse, mutect2, varscan2
- AMIGO2 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV56975899; called by muse, mutect2
- ANGPT4 | c.517T>C p.S173P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67923251; called by muse, mutect2, varscan2
- ANLN | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56080440; called by muse, mutect2, varscan2
- AOC1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV62871580; called by muse, mutect2, varscan2
- ASB5 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs760611722, COSV56675313; called by muse, mutect2, varscan2
- ASPM | c.6020A>C p.Y2007S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV54141446; called by muse, mutect2, varscan2
- ATP10D | c.513C>G p.C171W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); catalogued as COSV56714887; called by muse, varscan2
- BRINP1 | c.1299C>G p.N433K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV56316505; called by muse, mutect2, varscan2
- BRINP1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.807); catalogued as COSV56313745, COSV56316511; called by muse, mutect2, varscan2
- BTN2A1 | c.1361T>A p.L454Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57007007; called by muse, mutect2, varscan2
- CASP4 | c.902T>C p.I301T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV67745005; called by muse, mutect2, varscan2
- CD36 | c.724C>G p.H242D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV59221375; called by muse, mutect2, varscan2
- CDH7 | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59884758, COSV59897444; called by muse, mutect2, varscan2
- CEACAM8 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54992166; called by muse, mutect2, varscan2
- CHDH | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV55468893; called by muse, mutect2, varscan2
- CHMP4C | c.515A>T p.E172V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV51929428; called by muse, mutect2, varscan2
- CIDEA | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57601275; called by muse, mutect2, varscan2
- CLPTM1L | c.1037G>C p.S346T | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57993523; called by muse, mutect2
- CNGA3 | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV55629252; called by muse, mutect2, varscan2
- CNOT1 | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs866821373, COSV55323672; called by muse, mutect2, varscan2
- CRB1 | c.3296C>A p.T1099K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as CM1111051, COSV66334867; called by muse, mutect2, varscan2
- CRTC2 | c.2062C>A p.R688S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57841827, COSV57846253; called by muse, mutect2, varscan2
- CRYBG1 | c.4085T>C p.L1362P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs761878814, COSV64815373; called by muse, mutect2, varscan2
- CTIF | c.1276A>G p.S426G | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56493917; called by muse, mutect2, varscan2
- CYP39A1 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs796578990, COSV51500192; called by muse, mutect2
- DCDC2 | c.875A>T p.K292I | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65834363; called by muse, mutect2, varscan2
- DCHS1 | c.8570C>A p.P2857H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55000413; called by muse, mutect2, varscan2
- DIDO1 | c.3425G>A p.S1142N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56636384; called by muse, mutect2, varscan2
- DNAJB6 | c.175+1G>T p.X59_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV51101845; called by muse, mutect2, varscan2
- DNAJC22 | c.550C>G p.R184G | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.322); catalogued as COSV101222588, COSV67713147; called by muse, mutect2, varscan2
- DNAJC6 | c.2374A>T p.N792Y | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV54783483; called by muse, mutect2, varscan2
- DSG2 | c.3233G>C p.G1078A | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1064795829, COSV55204205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERC1 | c.788C>G p.T263R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61700915; called by muse, mutect2, varscan2
- FBXO30 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV52792859; called by muse, mutect2, varscan2
- FBXO32 | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71552520; called by muse, mutect2, varscan2
- FBXO43 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV71055857; called by muse, mutect2, varscan2
- FLNC | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV57967314; called by muse, mutect2, varscan2
- FOCAD | c.3443C>T p.S1148F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58109397; called by muse, mutect2, varscan2
- FUCA2 | c.319T>A p.F107I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50021380; called by muse, mutect2, varscan2
- FUT1 | c.977C>G p.A326G | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59570449; called by muse, mutect2, varscan2
- FUT9 | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV56159609; called by muse, mutect2, varscan2
- GALNT13 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.239); catalogued as COSV67243509; called by muse, mutect2, varscan2
- GLIS3 | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 223/250 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759183029, COSV100173446, COSV60938063; called by muse, mutect2, varscan2
- GPHN | c.2123G>C p.G708A (on ENST00000315266 / NM_001377519.1; = p.G741A on NM_020806.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59497167; called by muse, mutect2, varscan2
- GPRC6A | c.848T>A p.V283D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59955919, COSV59956676; called by muse, mutect2, varscan2
- GRIK4 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV70808573; called by muse, mutect2, varscan2
- H4C3 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV58091674; called by muse, mutect2, varscan2
- HCFC2 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV57560879; called by muse, mutect2, varscan2
- HECTD2 | c.1402C>G p.L468V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV53225796; called by muse, mutect2, varscan2
- IL17RD | c.713A>G p.H238R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV56344239; called by muse, mutect2, varscan2
- IL1RL2 | c.382T>A p.L128I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.364); catalogued as COSV51820165; called by muse, mutect2, varscan2
- IQCB1 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 14/210 reads (7%) | catalogued as rs1441832156, COSV60440009; called by muse, mutect2
- KCNQ2 | c.1699G>T p.V567F (on ENST00000359125 / NM_172107.4; = p.V539F on NM_004518.6) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60556170; called by muse, mutect2, varscan2
- KLHL21 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); catalogued as COSV66554410; called by muse, mutect2, varscan2
- KNL1 | c.4444G>A p.G1482R (on ENST00000346991 / NM_170589.5; = p.G1456R on NM_144508.5) | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.203); catalogued as COSV61161901; called by muse, mutect2, varscan2
- KRT32 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV56788742; called by muse, mutect2, varscan2
- LACRT | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV57689016; called by muse, mutect2
- LARP4 | c.1853G>T p.S618I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV53320940, COSV53328030; called by muse, mutect2, varscan2
- LCMT2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV59792077; called by muse, mutect2, varscan2
- LHFPL3 | c.589G>C p.G197R | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67824036; called by muse, mutect2, varscan2
- LRPPRC | c.1678-2A>C p.X560_splice | Splice Site (SNP) | VAF 37/103 reads (36%) | catalogued as COSV53244531; called by muse, mutect2, varscan2
- LRRC3B | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67523070; called by muse, mutect2, varscan2
- LRRCC1 | c.1595A>G p.E532G | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64486416; called by muse, mutect2, varscan2
- LRRK2 | c.6276A>T p.L2092F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV54175734; called by muse, mutect2, varscan2
- MACF1 | c.8189del p.Q2730Rfs*3 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | catalogued as rs1274457504; called by mutect2, pindel, varscan2
- MACROD2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as rs748621808, COSV54072076; called by muse, mutect2, varscan2
- MARCHF6 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1431071773, COSV56888437; called by muse, mutect2, varscan2
- MEI1 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV55909210; called by muse, mutect2, varscan2
- MSH5 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as COSV65212097; called by muse, mutect2, varscan2
- MTO1 | c.1790A>G p.Y597C (on ENST00000370300 / NM_133645.3; = p.Y572C on NM_012123.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV64775351; called by muse, mutect2, varscan2
- MUC17 | c.3064T>A p.S1022T | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60307710; called by muse, mutect2
- MVK | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV57333359; called by muse, mutect2, varscan2
- NLRP3 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV60232590, COSV60232995; called by muse, mutect2
- NOS3 | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99871876; called by muse, mutect2, varscan2
- NOTCH3 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209870761, COSV54654571; called by muse, mutect2, varscan2
- NT5DC1 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.229); catalogued as COSV54575205; called by muse, mutect2, varscan2
- OBSCN | c.9253G>T p.A3085S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV52805847; called by muse, mutect2
- OR7A17 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59415448; called by muse, mutect2, varscan2
- PAMR1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV53517630; called by muse, mutect2, varscan2
- PCDHGB7 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.15); catalogued as rs1561780035, COSV54056843; called by muse, mutect2, varscan2
- PDE9A | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs770883595, COSV52325745, COSV52333182; called by muse, mutect2, varscan2
- PDZD3 | c.1316G>C p.G439A (on ENST00000531114; = p.G359A on NM_024791.4) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52710822, COSV99424168; called by muse, mutect2, varscan2
- RANBP17 | c.2615C>T p.S872L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV66659150; called by muse, mutect2, varscan2
- RANBP6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 55/59 reads (93%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs769632096, COSV52391818; called by muse, mutect2, varscan2
- RHAG | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57704868, COSV57706417; called by muse, mutect2, varscan2
- SCIN | c.1015A>C p.I339L (on ENST00000297029 / NM_001112706.3; = p.I92L on NM_033128.3) | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51700403; called by muse, mutect2, varscan2
- SCN8A | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs768570935, COSV61980245; called by muse, mutect2, varscan2
- SCUBE1 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs752389163, COSV62617399; called by muse, mutect2, varscan2
- SERPINB8 | c.85T>C p.F29L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV54640902; called by muse, mutect2
- SIN3A | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1464138714, COSV64585649; called by muse, mutect2, varscan2
- SLC2A7 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV101280748, COSV68902560, COSV68902593; called by muse, mutect2, varscan2
- SLC6A5 | c.235T>A p.S79T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV54228518, COSV54231459, COSV54233766; called by muse, mutect2, varscan2
- SMURF1 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63160201; called by muse, mutect2, varscan2
- SNTB1 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV67330349; called by muse, mutect2, varscan2
- SPEN | c.3813A>C p.E1271D | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65368651; called by muse, mutect2, varscan2
- SSR3 | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV54021916; called by muse, mutect2, varscan2
- SYNE2 | c.5830C>G p.Q1944E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV59974977; called by muse, mutect2, varscan2
- SZT2 | c.4470G>A p.M1490I (on ENST00000634258 / NM_001365999.1; = p.M1433I on NM_015284.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65176054; called by muse, mutect2, varscan2
- TMEM132D | c.1050T>A p.D350E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV70624789; called by muse, mutect2, varscan2
- TP63 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 112/285 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs558374141, COSV53218998; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC3 | c.339-2A>T p.X113_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV61297752; called by muse, mutect2, varscan2
- TTN | c.12448del p.A4150Lfs*3 (on ENST00000591111; = p.A4104Lfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | catalogued as COSV100614046; called by mutect2, pindel, varscan2
- UPRT | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 85/124 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV64912748; called by muse, mutect2, varscan2
- XDH | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV65151668; called by muse, mutect2, varscan2
- XPNPEP3 | c.1208A>C p.K403T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV63210243; called by muse, mutect2, varscan2
- ZDHHC2 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.255); catalogued as COSV50500511; called by muse, mutect2, varscan2
- ZFP36L2 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56698042, COSV56698102; called by muse, mutect2, varscan2
- ZNF256 | c.1109A>G p.Q370R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.344); catalogued as COSV56600355; called by muse, mutect2, varscan2
- ZNF430 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV55113374; called by muse, mutect2
- ZNF510 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs772165100, COSV56299509; called by muse, mutect2, varscan2
- ZNF586 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.413); catalogued as rs1264822084, COSV66972838; called by muse, mutect2, varscan2
- IGHV7-81 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.367); called by muse, mutect2
- IGKV2-24 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 104/225 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- IGKV2-24 | c.306G>T p.R102S | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- KRTAP10-4 | c.213del p.C72Vfs*108 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- MFSD11 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- SNRPF | c.62_82del p.V21_M27del | In Frame Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- TSC2 | c.5105_5108del p.I1702Sfs*123 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TYMP | c.239_263del p.L80Pfs*4 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.1467T>C p.I489= | Silent (SNP) | VAF 96/165 reads (58%) | catalogued as rs758415525, COSV51569720; called by muse, mutect2, varscan2
- AKR7A3 | c.324C>T p.D108= | Silent (SNP) | VAF 64/224 reads (29%) | catalogued as rs1467321831, COSV64389872; called by muse, mutect2, varscan2
- ARHGEF28 | c.654C>A p.V218= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV55273814; called by muse, mutect2, varscan2
- ATP13A5 | c.2559C>T p.N853= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs766721308, COSV60872351, COSV60877210; called by muse, mutect2, varscan2
- BAG6 | c.3120A>G p.E1040= (on ENST00000676571; = p.E993= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1195220483, COSV52996280; called by muse, mutect2, varscan2
- BNIPL | c.465C>A p.T155= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV54849539; called by muse, mutect2, varscan2
- CAD | c.3135T>G p.A1045= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV53033075; called by muse, mutect2, varscan2
- CASP5 | c.651G>T p.V217= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs904512432, COSV52832636; called by muse, mutect2, varscan2
- CELSR3 | c.2775G>A p.V925= | Silent (SNP) | VAF 72/144 reads (50%) | catalogued as rs200302496, COSV51182596; called by muse, mutect2, varscan2
- CLDN17 | c.102T>G p.A34= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV54522992; called by muse, mutect2, varscan2
- CSMD3 | c.7395T>C p.S2465= (on ENST00000297405 / NM_001363185.1; = p.S2361= on NM_052900.3) | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV52353155; called by muse, mutect2, varscan2
- DLG5 | c.4515C>T p.I1505= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV64950452; called by muse, mutect2, varscan2
- DYNC1H1 | c.12282G>A p.V4094= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV64144245; called by muse, mutect2, varscan2
- FLACC1 | c.249G>T p.V83= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53788299; called by muse, mutect2, varscan2
- GNE | c.1497G>A p.L499= (on ENST00000396594 / NM_001128227.3; = p.L468= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64953406; called by muse, mutect2, varscan2
- GPR84 | c.153C>G p.L51= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV57210581; called by muse, mutect2, varscan2
- GPRC5B | c.966G>A p.E322= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV56029232; called by muse, mutect2, varscan2
- IRF2BP2 | c.1236C>T p.T412= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV64015865; called by muse, mutect2, varscan2
- ITPR2 | c.3825G>A p.R1275= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV67277841; called by muse, mutect2, varscan2
- JPH3 | c.1947C>A p.G649= | Silent (SNP) | VAF 49/75 reads (65%) | catalogued as COSV52475323; called by muse, mutect2, varscan2
- LHFPL3 | c.369G>T p.V123= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV101308478; called by muse, mutect2
- LRFN5 | c.639C>T p.D213= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV53280222; called by muse, mutect2, varscan2
- MYO3A | c.3039C>G p.R1013= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV56353828; called by muse, mutect2, varscan2
- NKAPL | c.48T>C p.S16= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV59199754; called by muse, mutect2, varscan2
- OR4P4 | c.150C>A p.T50= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100111878, COSV58921848; called by muse, mutect2, varscan2
- PCDHA11 | c.1794G>A p.A598= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs372076650; called by muse, mutect2
- PNPLA8 | c.2166T>C p.S722= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV57555468; called by muse, mutect2, varscan2
- PPP2R3A | c.807T>C p.D269= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV53872466; called by muse, mutect2, varscan2
- PRAMEF19 | c.903T>G p.T301= | Silent (SNP) | VAF 21/335 reads (6%) | called by muse, mutect2
- RNF150 | c.513T>C p.I171= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV60801659; called by muse, mutect2, varscan2
- SCN11A | c.2175T>A p.R725= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV56580372; called by muse, mutect2, varscan2
- SLC17A1 | c.1329C>G p.G443= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55083152; called by muse, mutect2, varscan2
- TTF1 | c.1362G>A p.A454= | Silent (SNP) | VAF 47/81 reads (58%) | catalogued as rs61741946, COSV57507980; called by muse, mutect2, varscan2
- USP34 | chr2:61186656 T>A | 3'Flank (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
